Somatic mutation profile of tumor specimen TCGA-CJ-4901-01A (aliquot TCGA-CJ-4901-01A-01D-1429-08) from TCGA case TCGA-CJ-4901, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 47.6 years (17,396 days).
Specimen TCGA-CJ-4901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef9d1293-7aae-4f82-b0b5-81a9e52d270f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4901-11A (Solid Tissue Normal), aliquot TCGA-CJ-4901-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe3387b4-24ba-47da-ab50-f6b47c674960

The open-access MAF lists 57 somatic variants for this specimen: 48 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 7, Frame Shift Del 4, In Frame Del 2, Splice Site 1, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | catalogued as rs74315499, CM930516, COSV104404659, COSV58520213; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC093827.5 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as COSV55744631; called by muse, mutect2, varscan2
- ADH1B | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs140683864; called by muse, mutect2, varscan2
- AL121899.2 | c.1471A>G p.M491V | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV67349740; called by muse, mutect2
- ANKFN1 | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs866640368, COSV59441189; called by muse, mutect2, varscan2
- ANKS1B | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61335658; called by muse, mutect2, varscan2
- ATP6V1A | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56360996; called by muse, mutect2, varscan2
- CADM2 | c.604A>T p.I202F (on ENST00000407528 / NM_001167674.2; = p.I204F on NM_153184.4) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV67358126; called by muse, mutect2
- CAMKK1 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50114041; called by muse, mutect2
- COL27A1 | c.2710G>A p.G904R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375632196, COSV100621205, COSV61921648; called by muse, mutect2, varscan2
- CSMD3 | c.9148+1G>T p.X3050_splice (on ENST00000297405 / NM_001363185.1; = p.X2881_splice on NM_052900.3) | Splice Site (SNP) | VAF 103/315 reads (33%) | catalogued as COSV52105444; called by muse, mutect2, varscan2
- CTAGE1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs764512165, COSV66942909; called by muse, mutect2, varscan2
- CTR9 | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63727833; called by muse, mutect2, varscan2
- CTSB | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV61540344; called by muse, mutect2, varscan2
- DOCK4 | c.1656C>A p.F552L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV70233636, COSV70234757; called by muse, mutect2
- EPB41L3 | c.2084C>T p.T695M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373780287, COSV100549187; called by muse, mutect2, varscan2
- ESM1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV67318301; called by muse, mutect2, varscan2
- FARSA | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV58904346; called by muse, mutect2, varscan2
- GEMIN8 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV60550074; called by muse, mutect2, varscan2
- GPR171 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV56368793; called by muse, mutect2
- HNRNPK | c.1068A>T p.E356D | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.251); catalogued as COSV61088279; called by muse, mutect2, varscan2
- MYO3A | c.2207T>C p.I736T | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56320255; called by muse, mutect2, varscan2
- NPAS4 | c.208T>A p.S70T | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV60648890; called by muse, mutect2, varscan2
- NRXN1 | c.1511T>A p.I504K | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58437341; called by muse, mutect2, varscan2
- P2RY2 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60775401; called by muse, mutect2, varscan2
- PCDHB16 | c.1883G>T p.R628M | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53357844; called by muse, mutect2, varscan2
- PRR27 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 79/561 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV60640141; called by muse, mutect2, varscan2
- RAPGEF2 | c.4130A>T p.H1377L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as COSV52424589; called by muse, mutect2
- RGS11 | c.736G>A p.V246I (on ENST00000397770 / NM_183337.3; = p.V225I on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs377094004, COSV51451467; called by muse, mutect2, varscan2
- SERPINI2 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.988); catalogued as COSV52984339; called by muse, mutect2
- SOX2 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV57620924; called by muse, mutect2
- SPATA20 | c.1676C>T p.P559L (on ENST00000356488 / NM_001258372.1; = p.P575L on NM_022827.4) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50065824; called by muse, mutect2, varscan2
- TLN1 | c.7349C>T p.S2450L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs913381794, COSV59204239; called by muse, mutect2, varscan2
- TMEM245 | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63026234; called by muse, mutect2, varscan2
- TRIOBP | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV60373669, COSV60375403; called by muse, mutect2, varscan2
- TRPC1 | c.1375A>T p.S459C (on ENST00000476941 / NM_001251845.2; = p.S425C on NM_003304.4) | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV56422953; called by muse, mutect2, varscan2
- TSPAN19 | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV70813382, COSV70814440; called by muse, mutect2, varscan2
- TTN | c.69227C>T p.A23076V (on ENST00000591111; = p.A15652V on NM_003319.4) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | PolyPhen benign (0.009); catalogued as COSV59893550; called by muse, mutect2, varscan2
- ZGRF1 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV52198986; called by muse, mutect2, varscan2
- ZNF415 | c.903A>T p.K301N | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV54699132; called by muse, mutect2
- ZNF594 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 49/378 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV68384745; called by muse, varscan2
- ZNF800 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56173723; called by muse, mutect2
- ACOT2 | c.164del p.Q55Rfs*13 | Frame Shift Del (DEL) | VAF 60/237 reads (25%) | called by mutect2, varscan2
- CRTAC1 | c.81_83delinsT p.S28Pfs*4 | Frame Shift Del (DEL) | VAF 29/220 reads (13%) | called by pindel, varscan2*
- DALRD3 | c.838_849del p.V280_V283del (on ENST00000341949 / NM_001009996.3; = p.V113_V116del on NM_018114.5) | In Frame Del (DEL) | VAF 21/205 reads (10%) | called by mutect2, pindel
- ECHDC3 | c.628del p.S210Lfs*34 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- SEPSECS | c.1160_1174del p.A387_L391del | In Frame Del (DEL) | VAF 9/99 reads (9%) | called by mutect2, pindel
- SPEN | c.852del p.S285Afs*81 | Frame Shift Del (DEL) | VAF 49/193 reads (25%) | called by pindel, varscan2
- ABCC4 | c.606G>T p.V202= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV65309762; called by muse, mutect2, varscan2
- DNAI3 | c.1431A>G p.G477= | Silent (SNP) | VAF 23/283 reads (8%) | catalogued as rs368650006, COSV54000642; called by muse, mutect2
- GDF10 | c.666C>T p.S222= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1342969265; called by muse, mutect2, varscan2
- IMPA2 | c.153A>T p.A51= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as COSV52318763; called by muse, mutect2, varscan2
- OR4K14 | c.153T>A p.S51= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV59292128; called by muse, mutect2, varscan2
- OR51B4 | c.72G>C p.R24= | Silent (SNP) | VAF 26/223 reads (12%) | catalogued as COSV66516780; called by muse, mutect2, varscan2
- PLEKHG4 | c.3255G>A p.P1085= | Silent (SNP) | VAF 19/330 reads (6%) | catalogued as rs781091450, COSV58571198; called by muse, mutect2
- ETNK1 | c.-255C>A | 5'UTR (SNP) | VAF 6/43 reads (14%) | catalogued as COSV56883845, COSV99861118; called by muse, mutect2
- PRR12 | c.52-525G>A | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as rs1305188179, COSV69816638; called by muse, mutect2, varscan2
